Somatic mutation profile of tumor specimen TCGA-VM-A8C8-01A (aliquot TCGA-VM-A8C8-01A-11D-A36O-08) from TCGA case TCGA-VM-A8C8, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 50.6 years (18,494 days).
Specimen TCGA-VM-A8C8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44c45ed7-d210-4b8b-a061-908b108aba0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VM-A8C8-10A (Blood Derived Normal), aliquot TCGA-VM-A8C8-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f1c4c7f-28e1-4434-b717-7af740f8dcca

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 13, Nonsense Mutation 2, In Frame Del 1, Frame Shift Del 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 42/94 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 30/40 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AK9 | c.2996C>T p.P999L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as rs772963198, COSV100393876; called by muse, mutect2, varscan2
- AKAP4 | c.266A>G p.D89G | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100654278; called by muse, mutect2, varscan2
- ATRX | c.1960C>T p.R654* | Nonsense Mutation (SNP) | VAF 89/253 reads (35%) | catalogued as COSV64870592, COSV64871923; called by muse, mutect2, varscan2
- CHD9 | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.241); catalogued as COSV101272144; called by muse, mutect2, varscan2
- CLEC5A | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs782280521, COSV101407772; called by muse, mutect2, varscan2
- COX10 | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs201424119, COSV99886621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CST4 | c.231C>T p.T77= | Splice Region (SNP) | VAF 44/195 reads (23%) | catalogued as COSV54150174; called by muse, mutect2, varscan2
- DMXL1 | c.5237G>T p.R1746L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.138); catalogued as rs779107340, COSV100224132; called by muse, mutect2, varscan2
- DNMT3B | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as CM002946, COSV52415711; called by muse, mutect2, varscan2
- GJB4 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs370286559, COSV58355851; called by muse, mutect2, varscan2
- MYCBP2 | c.1134A>C p.L378F (on ENST00000357337; = p.L416F on NM_015057.5) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100630529; called by muse, mutect2, varscan2
- NAALADL2 | c.989A>G p.D330G | Missense Mutation (SNP) | VAF 83/159 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775784729, COSV101380197; called by muse, mutect2, varscan2
- NAT16 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV100296299; called by muse, mutect2, varscan2
- PARP3 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs756366078, COSV51756130, COSV99232471; called by muse, mutect2, varscan2
- PORCN | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as CM095736, COSV100400452; called by muse, mutect2, varscan2
- PPL | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as rs1045541349, COSV100630831; called by muse, mutect2, varscan2
- PTPN11 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100692718; called by muse, mutect2
- SLITRK2 | c.127A>G p.N43D | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.377); catalogued as COSV100157828; called by muse, mutect2, varscan2
- SPPL2A | c.926A>T p.E309V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV99961631; called by muse, mutect2, varscan2
- SRD5A2 | c.591G>C p.E197D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as CM920639, COSV99252426; called by muse, mutect2
- STOX2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1395066454, COSV100408774; called by muse, mutect2
- TIMM23 | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 43/321 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs1424163031; called by muse, mutect2, varscan2
- TLN1 | c.5153A>G p.N1718S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs202143177, COSV100147804; called by muse, mutect2, varscan2
- TMPRSS15 | c.2344A>G p.T782A | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99518096; called by muse, mutect2, varscan2
- UCK1 | c.571del p.V191* | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as COSV100944113, COSV64735581; called by mutect2, pindel, varscan2
- USP47 | c.2180C>T p.S727F (on ENST00000399455 / NM_001372095.1; = p.S639F on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV100359628; called by muse, mutect2, varscan2
- WDR74 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV99586929; called by muse, mutect2, varscan2
- IGBP1P2 | c.946C>T p.L316F | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ITPRID2 | c.2825_2851del p.P942_V950del | In Frame Del (DEL) | VAF 12/96 reads (13%) | called by mutect2, pindel
- CLEC4G | c.837C>T p.D279= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100183670; called by muse, mutect2
- COL5A3 | c.4242G>A p.P1414= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs537422545, COSV99318247; called by muse, mutect2, varscan2
- COL6A3 | c.3870C>T p.S1290= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99798669; called by muse, mutect2, varscan2
- CRTC2 | c.1110C>G p.P370= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs544579417, COSV100339136; called by muse, mutect2, varscan2
- INO80 | c.3381C>T p.T1127= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV100731858; called by muse, mutect2, varscan2
- KIR3DL2 | c.846G>A p.L282= | Silent (SNP) | VAF 54/215 reads (25%) | called by muse, mutect2, varscan2
- NSDHL | c.615C>T p.G205= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV100938658; called by muse, mutect2, varscan2
- NWD1 | c.3300C>T p.A1100= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs201898485, COSV100342784, COSV100343426; called by muse, mutect2, varscan2
- PREX2 | c.891T>C p.R297= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as COSV55748725, COSV99907651; called by muse, mutect2, varscan2
- PTPDC1 | c.714G>A p.R238= (on ENST00000375360 / NM_177995.3; = p.R290= on NM_152422.4) | Silent (SNP) | VAF 30/139 reads (22%) | catalogued as COSV99997652; called by muse, mutect2, varscan2
- RHPN1 | c.1317G>C p.V439= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100000700; called by muse, mutect2
- SLC6A1 | c.1071G>A p.A357= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs1139553, COSV55116944; ClinVar: likely benign; called by muse, mutect2, varscan2
- TKFC | c.846C>T p.D282= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs1365049470, COSV67523547; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498351 del TG | 5'Flank (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
